Somatic mutation profile of tumor specimen 0DNCOS from CCDI case PBBYCP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pleuropulmonary blastoma; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 0.0 years (2 days).
Specimen 0DNCOS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f21bbe8a-e9ab-431e-a967-c4462d52979c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNCGU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aedbd694-378a-4fe0-aff7-13f35ccea86f

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 82/370 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 12/189 reads (6%) | called by muse, mutect2
- POU3F1 | c.*9G>C | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
